Gene-level copy-number profile of tumor specimen HTMCP-03-06-02074-01B from CGCI case HTMCP-03-06-02074, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 63.8 years (23,305 days).
Specimen HTMCP-03-06-02074-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6a6cd1bc-aa43-4b94-ab51-6fdaaeadd3d4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02074-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/590abb44-35e7-4253-a14b-907166c256cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 924; copy number 2: 24,511; copy number 3: 21,523; copy number 4: 9,937; copy number 5: 747; copy number 6: 16; copy number 7: 19; copy number 8: 207; copy number 9: 396; copy number 10: 103.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr5:177,782,197–177,803,344, 2 genes (within-gene range 0–2): AC140125.2, AC140125.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,488 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:97,618,638–99,490,035, 38 genes, copy number 5: AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1.
- chr3:109,915,976–109,977,767, 2 genes, copy number 7: NFYBP1, AC078918.1.
- chr3:136,148,917–137,011,085, 18 genes, copy number 5: MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1.
- chr3:196,142,525–198,123,232, 77 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 8–10 (broad region; genes not listed).
- chr5:82,765,404–83,875,821, 23 genes, copy number 5: AC008885.2, RPL5P16, AC008885.1, LINC01338, AC108174.1, AC027338.2, ST13P12, AC027338.1, AC104118.1, TMEM167A, SCARNA18, XRCC4, AC094085.1, COQ10BP2, FTH1P9, VCAN, VCAN-AS1, HAPLN1, RN7SKP295, RNU6-620P, AC020899.1, RNU4-11P, ZP3P1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:90,001,324–90,502,239, 29 genes, copy number 5: ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1.
- chr16:32,289,547–33,622,547, 64 genes, copy number 5–7 (broad region; genes not listed).
- chr16:69,355,567–69,408,571, 1 gene, copy number 5 (within-gene range 4–5): TERF2.
- chr17:16,829,999–16,832,830, 1 gene, copy number 5: KRT16P2.
- chr20:87,250–462,543, 16 genes, copy number 5: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA.
- chr20:31,580,890–31,607,240, 4 genes, copy number 5: AL110115.2, RNU6-384P, ID1, MIR3193.
- chr21:34,787,801–36,079,389, 15 genes, copy number 6 (within-gene range 3–6): RUNX1, AP000331.1, AF015262.1, RPL34P3, EZH2P1, AF015720.1, MIR802, RPS20P1, PPP1R2P2, LINC01436, RPL23AP3, SETD4, RIMKLBP1, SETD4-AS1, RNU6-992P.
- chr21:36,069,941–36,073,166, 1 gene, copy number 6 (within-gene range 3–6): CBR1.
- chr21:36,632,681–38,121,345, 27 genes, copy number 8 (within-gene range 1–8): AP000696.1, AP000697.1, SIM2, HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1, AP001437.2, AP001437.1, DYRK1A, AP001407.1, KCNJ6, KCNJ6-AS1.
- chr22:27,716,480–32,039,896, 161 genes, copy number 5 (broad region; genes not listed).
- chr22:35,119,824–35,231,056, 1 gene, copy number 5 (within-gene range 3–5): LINC01399.
- chr22:35,164,304–36,537,604, 46 genes, copy number 5: Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1, MYH9, MIR6819, Z82215.1, FO393418.1, RPS15AP38, Y_RNA, AL022313.2, TXN2, FOXRED2, EIF3D, AL022313.1.
- chr22:37,550,026–43,187,134, 235 genes, copy number 5 (broad region; genes not listed).
- chr22:45,192,244–46,762,563, 46 genes, copy number 5: KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1.

Autosomal genes at a single copy (total copy number 1): 924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
